Gene-level copy-number profile of specimen HCM-BROD-0578-C15-85A from HCMI case HCM-BROD-0578-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IV; Tumor grade: GX; Age at diagnosis: 46.7 years (17,054 days).
Specimen HCM-BROD-0578-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 12.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1e759d46-d23c-4ba7-a153-c085b096315e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0578-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/167dba82-a775-42d4-85c6-c73388cf4af6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 12,376; copy number 2: 43,735; copy number 3: 1,922; copy number 4: 89; copy number 5: 433; copy number 6: 3; copy number 7: 6; copy number 8: 2; copy number 9: 10; copy number 10: 21; copy number 11: 7; copy number 12: 25; copy number 13: 96; copy number 14: 35; copy number 15: 6; copy number 17: 11; copy number 20: 80; copy number 21: 32; copy number 22: 12; copy number 24: 5; copy number 25: 4.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 788 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–145,918,717, 85 genes, copy number 5 (broad region; genes not listed).
- chr7:65,647,010–65,770,810, 2 genes, copy number 7 (within-gene range 3–7): AC073107.1, INTS4P2.
- chr12:55,311,835–62,622,213, 227 genes, copy number 5–6 (within-gene range 5–7) (broad region; genes not listed).
- chr12:63,055,275–63,360,037, 5 genes, copy number 5: RSL24D1P5, AVPR1A, AC135584.1, HNRNPA1P69, AC026116.1.
- chr12:63,623,788–64,507,329, 29 genes, copy number 5 (within-gene range 4–5): AC084357.2, AC027667.1, AC084357.3, AC084357.1, RXYLT1, RXYLT1-AS1, PABPC1P4, SRGAP1, RPL36AP41, AC079866.2, AC079866.1, AC020611.1, AC020611.2, AC025576.3, AC025576.2, AC025576.1, C12orf66, RNU6-1009P, AC012158.1, RNU5A-7P, C12orf56, OOEPP2, ATP6V1E1P3, AC135279.1, XPOT, AC135279.2, AC135279.3, TBK1, AC136977.1.
- chr12:65,017,468–71,118,247, 125 genes, copy number 5–25 (broad region; genes not listed).
- chr20:44,355,700–45,641,370, 60 genes, copy number 5–15: HNF4A, HNF4A-AS1, AL117382.2, MIR3646, LINC01620, RPL37AP1, TTPAL, SERINC3, PKIG, ADA, LINC01260, AL139352.1, KCNK15-AS1, CCN5, KCNK15, AL118522.1, RIMS4, PGBD4P2, YWHAB, PABPC1L, TOMM34, STK4-AS1, STK4, Y_RNA, KCNS1, WFDC5, WFDC12, PI3, SEMG1, SEMG2, AL035660.1, AL035660.2, SLPI, MATN4, RBPJL, SDC4, AL021578.1, SYS1, SYS1-DBNDD2, TP53TG5, NDUFB4P10, DBNDD2, PIGT, MIR6812, AL031663.3, WFDC2, AL031663.2, RPL5P2, SPINT3, WFDC6, EPPIN-WFDC6, AL031663.1, HSPD1P21, EPPIN, WFDC8, RNA5SP485, CCNB1IP1P2, WFDC9, WFDC10A, RPS2P7.
- chr20:49,903,391–62,861,822, 251 genes, copy number 5–21 (broad region; genes not listed).
- chr21:8,762,386–8,880,976, 4 genes, copy number 5: CR381670.2, SNX18P10, MTCO1P1, CR381670.1.

Autosomal genes at a single copy (total copy number 1): 9,520. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
